Surgical pathology report (de-identified scan), TCGA case TCGA-05-4389, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4389-01A (Primary Tumor).

█
█:

Mixed bronchopulmonary adenocarcinoma.

Comment/supplementary remark: histoarchitecture and cell morphology of the tumor are consistent with a bronchopulmonary origin of the tumor. This will be reviewed and confirmed in immunohistological investigations. The tumor is completely removed by wedge excision of sample 1.). The visceral pleura, the right upper lobe of sample 2.), including its resection margin of the bronchus and vessels and all the lymph nodes removed are tumor-free. On the assumption of a bronchopulmonary origin to the tumor: Tumor classification: pT1, pN0, R0, stage IA..

C 34.1 M 8255/3.

Source: NCI Genomic Data Commons file cdd82929-899f-4f42-9250-267b797be8cf (TCGA-05-4389.924F5877-07DC-48DC-B920-C59BA743498E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).